Somatic mutation profile of cancer-model specimen HCM-BROD-0214-C71-85A (Adherent Cell Line, passage 10; aliquot HCM-BROD-0214-C71-85A-01D-A79L-36), derived from the recurrence tumor of HCMI case HCM-BROD-0214-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 43.4 years (15,870 days).
Specimen HCM-BROD-0214-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b69ed5be-6528-4262-8089-a7faa8bc2ed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0214-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0214-C71-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf8e3d04-53e1-44d0-9985-002ebbcc9a2b

The open-access MAF lists 117 somatic variants for this specimen: 82 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 31, Frame Shift Del 12, Nonsense Mutation 5, 5'UTR 2, Intron 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 229/229 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs763997055, COSV100735848; called by muse, mutect2, varscan2
- ABCA13 | c.1352T>A p.L451H | Missense Mutation (SNP) | VAF 151/487 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV70028842; called by muse, mutect2, varscan2
- AL772284.1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 81/743 reads (11%) | SIFT deleterious (0.04); catalogued as COSV68180042; called by muse, mutect2, varscan2
- AR | c.2136G>T p.Q712H | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65961179; called by muse, mutect2
- CLCNKA | c.1972G>C p.V658L | Missense Mutation (SNP) | VAF 33/433 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV58890438; called by muse, mutect2
- CLTCL1 | c.4758del p.W1587Gfs*16 (on ENST00000427926 / NM_007098.4; = p.W1530Gfs*16 on NM_001835.4) | Frame Shift Del (DEL) | VAF 51/277 reads (18%) | catalogued as COSV53205606; called by mutect2, pindel, varscan2
- CREBBP | c.3698G>T p.R1233M | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99270741; called by muse, mutect2
- CTSG | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 146/377 reads (39%) | catalogued as COSV53534764; called by muse, mutect2, varscan2
- DIXDC1 | c.938C>G p.S313C (on ENST00000440460 / NM_001037954.4; = p.S102C on NM_033425.4) | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782108521; called by muse, mutect2, varscan2
- DNAH6 | c.5614C>A p.Q1872K | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV52868251; called by muse, mutect2, varscan2
- ELFN1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 96/818 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539135349, COSV70036942; called by muse, mutect2, varscan2
- FAP | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 128/228 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141855900, COSV51865909; called by muse, mutect2, varscan2
- FHAD1 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 79/336 reads (24%) | catalogued as COSV62710933; called by muse, mutect2, varscan2
- FMR1NB | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs782811149, COSV65071435; called by muse, mutect2, varscan2
- FREM3 | c.5944G>A p.V1982I | Missense Mutation (SNP) | VAF 182/234 reads (78%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as rs954270962, COSV61682060; called by muse, mutect2, varscan2
- FRY | c.8960G>A p.R2987Q | Missense Mutation (SNP) | VAF 394/396 reads (99%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs376374665; called by muse, varscan2
- GRM3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 355/914 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs571579021, COSV64471709, COSV64473083; called by muse, mutect2, varscan2
- KIAA0753 | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 201/202 reads (100%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1367348426; called by muse, mutect2, varscan2
- LRRC4C | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV53417806, COSV53419233; called by muse, mutect2, varscan2
- LYST | c.4322_4325del p.E1441Vfs*12 | Frame Shift Del (DEL) | VAF 186/354 reads (53%) | catalogued as rs1324833938; called by mutect2, pindel, varscan2
- MED12 | c.4725C>A p.N1575K | Missense Mutation (SNP) | VAF 28/361 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs1556338296; ClinVar: uncertain significance; called by muse, mutect2
- MUC16 | c.43237C>T p.R14413W | Missense Mutation (SNP) | VAF 193/393 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.981); catalogued as rs367839339; called by muse, mutect2, varscan2
- NF1 | c.3822_3823del p.F1275Pfs*8 | Frame Shift Del (DEL) | VAF 138/290 reads (48%) | catalogued as rs1555615472; called by pindel, varscan2
- NSFL1C | c.752A>G p.K251R | Missense Mutation (SNP) | VAF 131/333 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs763661840; called by muse, mutect2, varscan2
- OR10H5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 170/677 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs535367686; called by muse, mutect2, varscan2
- PAX7 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 194/510 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs759517187; called by muse, mutect2, varscan2
- PENK | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 158/343 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs759815705, COSV59240234; called by muse, mutect2, varscan2
- PLPPR2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 202/454 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99264481; called by muse, mutect2, varscan2
- PPP1R12A | c.2188del p.E730Rfs*58 | Frame Shift Del (DEL) | VAF 59/223 reads (26%) | catalogued as COSV54111971; called by mutect2, pindel, varscan2
- PRR36 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 368/694 reads (53%) | SIFT deleterious, low confidence (0.03); catalogued as rs1004693591; called by muse, mutect2, varscan2
- PTEN | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 62/63 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64293021, COSV64299567; called by muse, mutect2, varscan2
- RALGAPA1 | c.3307G>A p.D1103N | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV51885662; called by muse, mutect2
- RASGEF1C | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as rs767268071; called by muse, mutect2, varscan2
- RB1 | c.1811A>G p.D604G | Missense Mutation (SNP) | VAF 164/164 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV57304305; called by muse, mutect2, varscan2
- RBM3 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs781917689; called by muse, mutect2, varscan2
- SLC25A26 | c.197C>A p.A66E | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); catalogued as rs1454752501; called by muse, mutect2, varscan2
- SPHKAP | c.2426C>T p.T809M | Missense Mutation (SNP) | VAF 170/318 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs200506306; called by muse, mutect2, varscan2
- TCEAL7 | c.188C>A p.T63K | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV60125153; called by muse, mutect2, varscan2
- VAV3 | c.1769T>G p.V590G | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1270697072; called by muse, mutect2, varscan2
- ZNF263 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs888383569; called by muse, mutect2, varscan2
- ACTN1 | c.2319del p.C774Afs*23 | Frame Shift Del (DEL) | VAF 40/428 reads (9%) | called by mutect2, pindel
- AGRN | c.5139C>G p.I1713M | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ARSL | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 65/543 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ATP6AP1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- BCOR | c.1307del p.V436Afs*6 | Frame Shift Del (DEL) | VAF 163/429 reads (38%) | called by mutect2, pindel*, varscan2
- CACNA1E | c.3087C>A p.S1029R | Missense Mutation (SNP) | VAF 378/657 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CATSPERB | c.2078T>G p.F693C | Missense Mutation (SNP) | VAF 228/528 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CCDC38 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CCNL1 | c.329del p.L110Cfs*37 | Frame Shift Del (DEL) | VAF 130/472 reads (28%) | called by mutect2, varscan2
- CDK13 | c.367del p.L123Cfs*18 | Frame Shift Del (DEL) | VAF 298/1112 reads (27%) | called by mutect2, pindel, varscan2
- CEACAM18 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 171/389 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CEP295 | c.7491G>T p.R2497S | Missense Mutation (SNP) | VAF 102/175 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP47 | c.5275A>T p.N1759Y | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); called by muse, mutect2
- DDX60 | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DST | c.17864T>C p.I5955T (on ENST00000361203 / NM_001374722.1; = p.I3652T on NM_015548.5) | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.839); called by muse, mutect2
- F13B | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLG2 | c.2126A>C p.H709P | Missense Mutation (SNP) | VAF 119/372 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- GEMIN2 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GIGYF2 | c.843_844del p.D281Efs*3 | Frame Shift Del (DEL) | VAF 139/352 reads (39%) | called by mutect2, pindel, varscan2
- GOLGA2 | c.1875T>G p.H625Q | Missense Mutation (SNP) | VAF 46/420 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HHIP | c.776A>G p.E259G | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- IGHV2-26 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 223/385 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KSR2 | c.1701C>G p.Y567* | Nonsense Mutation (SNP) | VAF 35/468 reads (7%) | called by muse, mutect2
- MET | c.1978A>G p.T660A | Missense Mutation (SNP) | VAF 110/430 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- NLRP9 | c.836_839del p.A279Gfs*14 | Frame Shift Del (DEL) | VAF 163/418 reads (39%) | called by mutect2, pindel, varscan2
- PAK4 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 93/874 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.516T>A p.Y172* (on ENST00000374531 / NM_001037293.2; = p.Y204* on NM_053016.6) | Nonsense Mutation (SNP) | VAF 124/369 reads (34%) | called by muse, mutect2, varscan2
- PRDM9 | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC16A4 | c.1420T>C p.F474L | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLC34A2 | c.927+1del | Frame Shift Del (DEL) | VAF 120/176 reads (68%) | called by mutect2, pindel*, varscan2
- SLC8A3 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 83/444 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9C1 | c.776del p.C259Lfs*3 | Frame Shift Del (DEL) | VAF 76/143 reads (53%) | called by mutect2, pindel, varscan2
- SUGCT | c.1140G>T p.K380N (on ENST00000335693 / NM_001193313.2; = p.K406N on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/578 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by mutect2, varscan2
- TMUB1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 305/817 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TRPV2 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 85/295 reads (29%) | called by muse, mutect2, varscan2
- UTRN | c.915_917del p.E306del | In Frame Del (DEL) | VAF 37/449 reads (8%) | called by mutect2, pindel*
- VCPIP1 | c.1796_1799dup p.R601Wfs*14 | Frame Shift Ins (INS) | VAF 24/159 reads (15%) | called by mutect2, pindel, varscan2
- YBEY | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 268/554 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZNF142 | c.5632C>T p.P1878S (on ENST00000411696 / NM_001379660.1; = p.P1678S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 168/282 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); called by muse, mutect2
- ZNF514 | c.425A>T p.K142I | Missense Mutation (SNP) | VAF 141/310 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF674 | c.1120A>C p.K374Q | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- AC025287.4 | c.1185C>T p.S395= | Silent (SNP) | VAF 20/282 reads (7%) | called by muse, mutect2
- ADCY5 | c.2082G>A p.K694= | Silent (SNP) | VAF 197/256 reads (77%) | called by muse, mutect2, varscan2
- BX276092.9 | c.105C>T p.D35= | Silent (SNP) | VAF 28/518 reads (5%) | called by muse, mutect2
- CEACAM4 | c.666T>C p.Y222= | Silent (SNP) | VAF 64/593 reads (11%) | catalogued as rs995692068; called by muse, mutect2, varscan2
- CLSTN2 | c.2232C>T p.R744= | Silent (SNP) | VAF 170/441 reads (39%) | called by muse, mutect2, varscan2
- DUOX2 | c.3957A>C p.T1319= | Silent (SNP) | VAF 42/413 reads (10%) | called by muse, mutect2
- EYS | c.6900T>C p.G2300= | Silent (SNP) | VAF 32/406 reads (8%) | called by muse, mutect2
- FAM89A | c.114G>A p.A38= | Silent (SNP) | VAF 435/784 reads (55%) | called by muse, mutect2, varscan2
- FZD10 | c.585G>A p.P195= | Silent (SNP) | VAF 298/550 reads (54%) | called by muse, mutect2, varscan2
- GABRA1 | c.981T>C p.A327= | Silent (SNP) | VAF 165/496 reads (33%) | called by muse, mutect2, varscan2
- GALNT9 | c.438C>T p.Y146= | Silent (SNP) | VAF 14/275 reads (5%) | catalogued as rs576555785; called by muse, mutect2
- GNAO1 | c.402C>T p.D134= | Silent (SNP) | VAF 121/455 reads (27%) | called by muse, mutect2, varscan2
- GRIN2D | c.1698G>A p.A566= | Silent (SNP) | VAF 129/502 reads (26%) | catalogued as COSV54382908; called by muse, mutect2, varscan2
- IFT140 | c.2331C>A p.L777= | Silent (SNP) | VAF 239/489 reads (49%) | catalogued as COSV54154678; called by muse, mutect2, varscan2
- KCNJ1 | c.597G>T p.V199= | Silent (SNP) | VAF 41/331 reads (12%) | called by muse, mutect2, varscan2
- KRTAP1-5 | c.27T>C p.C9= | Silent (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- L1CAM | c.2721C>T p.S907= | Silent (SNP) | VAF 58/453 reads (13%) | catalogued as rs200799618, COSV62828463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH14 | c.3367C>A p.R1123= | Silent (SNP) | VAF 56/480 reads (12%) | catalogued as rs984856121; called by muse, mutect2, varscan2
- OR2G2 | c.594C>T p.N198= | Silent (SNP) | VAF 143/347 reads (41%) | catalogued as rs771755488, COSV60739725; called by muse, mutect2, varscan2
- OR51E2 | c.648C>T p.S216= | Silent (SNP) | VAF 96/349 reads (28%) | catalogued as COSV67808648; called by muse, mutect2, varscan2
- OTOP1 | c.1611C>T p.N537= | Silent (SNP) | VAF 236/284 reads (83%) | catalogued as rs200964011; called by muse, mutect2, varscan2
- PCNT | c.2592G>C p.L864= | Silent (SNP) | VAF 198/499 reads (40%) | called by muse, mutect2, varscan2
- PPL | c.4245G>A p.E1415= | Silent (SNP) | VAF 164/584 reads (28%) | called by muse, mutect2, varscan2
- PTS | c.438G>A p.*146= | Silent (SNP) | VAF 63/107 reads (59%) | called by muse, mutect2, varscan2
- RIMS1 | c.321C>T p.G107= | Silent (SNP) | VAF 164/365 reads (45%) | catalogued as rs1408660383, COSV53462605; called by muse, mutect2, varscan2
- RTL1 | c.3786C>T p.N1262= | Silent (SNP) | VAF 369/650 reads (57%) | catalogued as rs552116769, COSV101128403; called by muse, mutect2, varscan2
- SYNE3 | c.2289G>A p.S763= | Silent (SNP) | VAF 28/417 reads (7%) | catalogued as rs149622983; called by muse, mutect2
- TPSB2 | c.825G>A p.P275= | Silent (SNP) | VAF 48/345 reads (14%) | catalogued as rs753650266, COSV99326694; called by muse, mutect2, varscan2
- UHRF1 | c.924C>T p.D308= (on ENST00000612630 / NM_001290050.1; = p.D321= on NM_013282.4) | Silent (SNP) | VAF 153/625 reads (24%) | catalogued as rs776763707, COSV53576281; called by muse, mutect2
- ZMYM3 | c.1278C>T p.S426= | Silent (SNP) | VAF 24/499 reads (5%) | catalogued as rs1569225987, COSV58741389; called by muse, mutect2
- ZNF346 | c.237C>T p.C79= | Silent (SNP) | VAF 22/398 reads (6%) | catalogued as rs200491700, COSV56156295; called by muse, mutect2
- HNRNPD | c.-260G>C | 5'UTR (SNP) | VAF 167/296 reads (56%) | called by muse, mutect2, varscan2
- LLCFC1 | c.158-45C>A | Intron (SNP) | VAF 414/1144 reads (36%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2492+4438G>A | Intron (SNP) | VAF 30/470 reads (6%) | catalogued as rs778369027, COSV57439427; called by muse, mutect2
- R3HDM1 | c.-156A>C | 5'UTR (SNP) | VAF 89/216 reads (41%) | called by muse, mutect2, varscan2
